Somatic mutation profile of tumor specimen TCGA-AN-A04D-01A (aliquot TCGA-AN-A04D-01A-21W-A050-09) from TCGA case TCGA-AN-A04D, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.7 years (21,426 days).
Specimen TCGA-AN-A04D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c0f0961-8574-4b72-ba46-03f320ba2bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A04D-10A (Blood Derived Normal), aliquot TCGA-AN-A04D-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f90b3b34-16b3-435c-bbf1-82a1450ec7f0

The open-access MAF lists 104 somatic variants for this specimen: 77 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 25, Frame Shift Del 3, In Frame Del 3, Nonsense Mutation 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs672601378, CM141567, COSV74204705, COSV74205512; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs372957171; called by muse, mutect2, varscan2
- ACOX3 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62712026; called by muse, mutect2, varscan2
- AKAP8 | c.1268C>G p.T423S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767177827, COSV54102571; called by muse, mutect2, varscan2
- ATAD2B | c.1827T>A p.C609* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV53198749; called by muse, mutect2, varscan2
- AZI2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55423932; called by muse, mutect2, varscan2
- C12orf40 | c.870C>A p.N290K | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV61132587; called by muse, mutect2, varscan2
- C4orf17 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV58512420; called by muse, mutect2, varscan2
- CD1C | c.285A>C p.L95F | Missense Mutation (SNP) | VAF 73/764 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272101380, COSV63806466, COSV63807349; called by muse, mutect2
- CEP170 | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV60509169; called by muse, mutect2, varscan2
- CFAP44 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.168); catalogued as COSV55611473; called by muse, mutect2, varscan2
- COL4A2 | c.3910G>A p.A1304T | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV64628393; called by muse, mutect2, varscan2
- COL4A5 | c.4557G>A p.M1519I | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100088194; called by muse, mutect2
- COL7A1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1189942401, COSV60393382; called by muse, mutect2, varscan2
- DDX55 | c.633C>G p.N211K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV53016146; called by muse, mutect2, varscan2
- DEFB112 | c.225T>A p.N75K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV59182575; called by muse, mutect2, varscan2
- DLGAP1 | c.2444A>C p.E815A | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59804470; called by muse, mutect2, varscan2
- ENPP7 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV60386546; called by muse, mutect2, varscan2
- EXO1 | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 98/361 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV62217599; called by muse, mutect2, varscan2
- F5 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV63124024; called by muse, mutect2, varscan2
- FAM98A | c.1157G>C p.G386A | Missense Mutation (SNP) | VAF 233/546 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.537); catalogued as COSV53210262; called by muse, mutect2, varscan2
- FCRL5 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62514588; called by muse, mutect2, varscan2
- GNPTAB | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1470903435, COSV54780011; called by muse, mutect2, varscan2
- GNPTG | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50190065; called by muse, mutect2, varscan2
- GON4L | c.2348C>G p.T783S | Missense Mutation (SNP) | VAF 95/405 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV55193672; called by muse, mutect2, varscan2
- HEATR3 | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99589994; called by muse, mutect2
- HUWE1 | c.8413G>C p.E2805Q | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.077); catalogued as COSV53371323; called by muse, mutect2
- ITGB4 | c.2795T>A p.M932K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV52325995, COSV99564264; called by muse, mutect2, varscan2
- KATNB1 | c.171+1G>A p.X57_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | catalogued as COSV65560372; called by muse, mutect2, varscan2
- KLHL38 | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58086849; called by muse, mutect2, varscan2
- KRTAP10-11 | c.295T>G p.C99G | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV58177898; called by muse, mutect2, varscan2
- LCA5L | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV55745288; called by muse, mutect2, varscan2
- LRBA | c.7937G>A p.R2646H | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1228840595, COSV63955669, COSV63966974; called by muse, mutect2, varscan2
- LSM14B | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 157/173 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV53380656, COSV53383504; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as rs758497517, COSV65419580; called by muse, mutect2
- MAPK4 | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV68542225; called by muse, mutect2, varscan2
- MTMR12 | c.170_172del p.T57_V58delinsI | In Frame Del (DEL) | VAF 40/84 reads (48%) | catalogued as COSV53784351; called by mutect2, pindel, varscan2
- MUC16 | c.22237G>A p.A7413T | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs1219284174, COSV67466538; called by muse, mutect2, varscan2
- MYNN | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 208/337 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62991334; called by muse, mutect2, varscan2
- NOS1AP | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62635034; called by muse, mutect2, varscan2
- OR10S1 | c.454A>T p.R152* | Nonsense Mutation (SNP) | VAF 38/157 reads (24%) | catalogued as COSV73342796; called by muse, mutect2, varscan2
- OR10V1 | c.880A>T p.R294W | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55697937; called by muse, mutect2, varscan2
- PCDHB2 | c.512A>T p.N171I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV52032668; called by muse, mutect2, varscan2
- PHACTR4 | c.1152T>G p.I384M (on ENST00000373839 / NM_001350159.2; = p.I394M on NM_023923.4) | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.143); catalogued as COSV65783958; called by muse, mutect2, varscan2
- PHC3 | c.684C>G p.S228R (on ENST00000494943 / NM_001308116.2; = p.S240R on NM_024947.4) | Missense Mutation (SNP) | VAF 120/503 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV71948715; called by muse, mutect2, varscan2
- PRICKLE4 | c.481T>A p.C161S (on ENST00000359201; = p.C201S on NM_013397.6) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59255204; called by muse, mutect2
- PWWP3A | c.137T>C p.L46P (on ENST00000627377; = p.L45P on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60902299; called by muse, mutect2
- RORC | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.694); catalogued as COSV59093054; called by muse, mutect2, varscan2
- RRP12 | c.3163G>C p.E1055Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59667581; called by muse, mutect2, varscan2
- SBSN | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748641353, COSV71733198; called by muse, mutect2, varscan2
- SLC16A12 | c.547A>G p.S183G | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57950063; called by muse, mutect2, varscan2
- SLC26A9 | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 87/469 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.417); catalogued as COSV61602766; called by muse, mutect2, varscan2
- SLC30A8 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 141/819 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV69970734; called by muse, mutect2, varscan2
- SNCAIP | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54410381; called by muse, mutect2, varscan2
- SPATS1 | c.151A>C p.S51R | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV55822315, COSV55823293, COSV99913433; called by muse, mutect2, varscan2
- SUGP1 | c.640del p.Y214Tfs*28 | Frame Shift Del (DEL) | VAF 44/100 reads (44%) | catalogued as COSV55921752; called by mutect2, pindel*, varscan2
- TANC2 | c.4787T>C p.V1596A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as COSV67334488; called by muse, mutect2, varscan2
- TCEAL5 | c.516A>T p.Q172H | Missense Mutation (SNP) | VAF 687/1692 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV101013156, COSV65503020; called by muse, mutect2, varscan2
- TCN2 | c.1206C>A p.N402K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53191455; called by muse, mutect2, varscan2
- TMEM131 | c.1780G>C p.V594L | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51776117; called by muse, mutect2, varscan2
- TTN | c.26795C>T p.T8932M (on ENST00000591111; = p.T8005M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen benign (0.003); catalogued as rs745792278, COSV60026005, COSV60085709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWNK | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV52968226; called by muse, mutect2, varscan2
- UCK2 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63315371; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV51955585; called by muse, mutect2, varscan2
- USH2A | c.6053T>A p.I2018K | Missense Mutation (SNP) | VAF 169/562 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV56370661; called by muse, mutect2, varscan2
- USPL1 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756082560, COSV55000003; called by muse, mutect2, varscan2
- VIT | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.299); catalogued as rs1408752091, COSV101007500; called by muse, mutect2
- VN1R2 | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV59038327; called by muse, mutect2, varscan2
- VNN2 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58472549; called by muse, mutect2, varscan2
- ZFP91 | c.1314dup p.F439Ifs*2 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | catalogued as rs1461308362; called by mutect2, pindel, varscan2
- ZNF710 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99184183; called by muse, mutect2
- CAPS | c.222_224del p.S74_G75delinsR | In Frame Del (DEL) | VAF 20/34 reads (59%) | called by mutect2, pindel, varscan2
- KRTAP24-1 | c.190_204del p.S64_A68del | In Frame Del (DEL) | VAF 38/106 reads (36%) | called by mutect2, pindel, varscan2
- RNF43 | c.1539_1551del p.K514Sfs*9 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- SI | c.3395del p.G1132Efs*52 | Frame Shift Del (DEL) | VAF 104/360 reads (29%) | called by mutect2, pindel, varscan2
- SLC35C2 | c.600_601insTGC p.T200_M201insC | In Frame Ins (INS) | VAF 39/136 reads (29%) | called by mutect2, pindel, varscan2
- SNTG1 | c.550-24_554del p.X184_splice | Splice Site (DEL) | VAF 34/93 reads (37%) | called by mutect2, pindel, varscan2
- ADAM12 | c.1173G>A p.V391= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV64106875; called by muse, mutect2, varscan2
- ANKRD30A | c.975T>A p.P325= (on ENST00000611781; = p.P269= on NM_052997.2) | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs756586414, COSV64610457, COSV64619182; called by muse, mutect2, varscan2
- C1QTNF9 | c.631C>T p.L211= | Silent (SNP) | VAF 63/168 reads (38%) | catalogued as COSV59657145; called by muse, mutect2, varscan2
- C1QTNF9B | c.631C>T p.L211= | Silent (SNP) | VAF 76/389 reads (20%) | catalogued as COSV65944129; called by muse, mutect2, varscan2
- CCNE1 | c.1095C>T p.D365= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as COSV52904470; called by muse, mutect2, varscan2
- CNTN2 | c.1668T>G p.P556= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV59350052; called by muse, mutect2
- CRNKL1 | c.282G>A p.E94= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV55629799; called by muse, mutect2, varscan2
- CROCC | c.1086G>A p.L362= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV65012089; called by muse, mutect2, varscan2
- DNAH10 | c.5805G>A p.L1935= (on ENST00000409039; = p.L1874= on NM_207437.3) | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV101292347; called by muse, mutect2
- GABRA4 | c.846A>G p.K282= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as COSV51927729; called by muse, mutect2, varscan2
- GLIS1 | c.642G>A p.R214= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV56548850; called by muse, mutect2, varscan2
- ICE1 | c.5163G>A p.P1721= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs778228625, COSV56825215; called by muse, mutect2, varscan2
- IL1RAPL2 | c.858G>A p.K286= | Silent (SNP) | VAF 96/356 reads (27%) | catalogued as COSV61158043; called by muse, mutect2, varscan2
- IPO9 | c.15G>A p.A5= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1338539197, COSV55216960; called by muse, varscan2
- ITGB5 | c.444G>C p.L148= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as COSV56149066; called by muse, mutect2, varscan2
- MBD5 | c.3400T>C p.L1134= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs1487878506, COSV68697052; called by muse, mutect2, varscan2
- MELTF | c.699G>T p.L233= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV56381426; called by muse, mutect2, varscan2
- PKD2L1 | c.45G>T p.L15= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV58396060; called by muse, mutect2
- PRAMEF18 | c.759A>G p.E253= | Silent (SNP) | VAF 84/231 reads (36%) | called by muse, mutect2, varscan2
- PRDM4 | c.1687C>T p.L563= | Silent (SNP) | VAF 89/206 reads (43%) | catalogued as COSV57305818; called by muse, mutect2, varscan2
- RUSC1 | c.2520C>G p.P840= (on ENST00000368352 / NM_001105203.2; = p.P371= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs757393770, COSV52739625; called by muse, mutect2, varscan2
- TDRD5 | c.2758T>C p.L920= | Silent (SNP) | VAF 44/177 reads (25%) | catalogued as COSV54242929; called by muse, mutect2, varscan2
- TNXB | c.12222G>A p.S4074= (on ENST00000647633; = p.S3827= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs773701143, COSV100926298, COSV64479058; called by muse, mutect2, varscan2
- TTN | c.20343C>G p.V6781= (on ENST00000591111; = p.V5854= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60067815; called by muse, mutect2, varscan2
- UBA1 | c.2286G>A p.L762= | Silent (SNP) | VAF 72/153 reads (47%) | catalogued as COSV60112764; called by muse, mutect2, varscan2
- PRKCA | c.1713+130G>C | Intron (SNP) | VAF 58/202 reads (29%) | catalogued as COSV66101504; called by muse, mutect2, varscan2
- TMEM140 | c.*1A>G | 3'UTR (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99313230; called by muse, mutect2, varscan2
